Somatic mutation profile of tumor specimen TCGA-PE-A5DE-01A (aliquot TCGA-PE-A5DE-01A-11D-A27P-09) from TCGA case TCGA-PE-A5DE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 41.7 years (15,216 days).
Specimen TCGA-PE-A5DE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4f269bb-0ca3-41ef-b2e6-1c4fd234535a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PE-A5DE-10A (Blood Derived Normal), aliquot TCGA-PE-A5DE-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8bb3d89-2110-4a2b-9005-54ef1d44614f

The open-access MAF lists 452 somatic variants for this specimen: 321 protein-altering or splice-affecting, 121 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 288, Silent 121, Nonsense Mutation 22, Splice Site 5, Intron 5, RNA 2, Nonstop Mutation 2, In Frame Del 1, 5'Flank 1, 3'UTR 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.2356-1G>C p.X786_splice | Splice Site (SNP) | VAF 5/45 reads (11%) | catalogued as rs1555290925, CS164068, COSV99666211, COSV99666331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCE1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56848478; called by muse, mutect2, varscan2
- ABT1 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99223191; called by muse, mutect2, varscan2
- ACAP2 | c.1611G>C p.K537N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV58753270; called by muse, mutect2
- ACCSL | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101122175; called by muse, mutect2, varscan2
- ADCK1 | c.693G>T p.R231S | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV99451533; called by muse, mutect2, varscan2
- ADH5 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV99596226; called by muse, mutect2, varscan2
- ADRA1A | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99370699; called by muse, mutect2, varscan2
- AEBP1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768189740, COSV99788720; called by muse, mutect2, varscan2
- AGAP2 | c.1184G>C p.S395T (on ENST00000547588 / NM_001122772.2; = p.S59T on NM_014770.4) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV99222955; called by muse, mutect2, varscan2
- AJM1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.443); catalogued as rs757182652, COSV99915589; called by muse, mutect2, varscan2
- AKAP13 | c.181G>C p.G61R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100773600; called by muse, mutect2, varscan2
- AKAP17A | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); catalogued as COSV100002162; called by muse, mutect2, varscan2
- AL121899.2 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101198433; called by muse, mutect2
- ALKBH1 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.416); catalogued as rs373180036, COSV99380538; called by muse, mutect2, varscan2
- ANO2 | c.1050G>C p.K350N (on ENST00000356134 / NM_001278597.3; = p.K354N on NM_001278596.3) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as COSV100500558, COSV59042847; called by muse, mutect2
- ANXA1 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV99973901; called by muse, mutect2, varscan2
- AP1B1 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757585860, COSV100434487; called by muse, mutect2, varscan2
- AP1G1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV100250331; called by muse, mutect2
- ASH1L | c.8502G>C p.K2834N (on ENST00000368346 / NM_001366177.2; = p.K2829N on NM_018489.3) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100853358, COSV64209543; called by muse, mutect2
- ATAD2 | c.1771G>C p.D591H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99784540; called by muse, mutect2, varscan2
- ATP2B3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs782614609, COSV54866290; called by muse, mutect2
- ATP8B2 | c.750G>T p.W250C (on ENST00000672630; = p.W217C on NM_001005855.2) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100527904; called by muse, mutect2, varscan2
- BAG5 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99914813; called by muse, mutect2, varscan2
- BCCIP | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | PolyPhen benign (0.165); catalogued as rs1225351859, COSV99501584; called by muse, mutect2, varscan2
- BCL2L11 | c.587G>C p.R196T (on ENST00000393256 / NM_138621.5; = p.R136T on NM_006538.5) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100427280; called by muse, mutect2, varscan2
- BRCA1 | c.4255G>A p.E1419K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100523939, COSV58788687; called by muse, mutect2, varscan2
- BTN1A1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as COSV99764322; called by muse, mutect2, varscan2
- C6 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.169); catalogued as rs764543477, COSV99666942; called by muse, mutect2, varscan2
- C9 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54676525, COSV99661981; called by muse, mutect2, varscan2
- CAMSAP2 | c.1171C>T p.H391Y (on ENST00000236925 / NM_001297707.2; = p.H380Y on NM_203459.3) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52676015, COSV99373240; called by muse, mutect2, varscan2
- CASP8 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV51848562, COSV51858129; called by muse, mutect2, varscan2
- CASR | c.2530G>A p.E844K (on ENST00000490131; = p.E921K on NM_000388.4) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs755629322, COSV56136433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCNB3 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99328866; called by muse, mutect2, varscan2
- CCT8L2 | c.1481G>A p.W494* | Nonsense Mutation (SNP) | VAF 18/135 reads (13%) | catalogued as rs1282087393, COSV100742695; called by muse, mutect2, varscan2
- CD5 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100759802; called by muse, mutect2, varscan2
- CD68 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs1179492523, COSV99548893; called by muse, mutect2, varscan2
- CDC45 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99596616; called by muse, mutect2
- CDH1 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99931793; called by muse, mutect2, varscan2
- CDKN1B | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV57431863; called by muse, mutect2, varscan2
- CDKN1B | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV57430816; called by muse, mutect2, varscan2
- CELSR2 | c.2020G>C p.D674H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99603666; called by muse, mutect2, varscan2
- CELSR2 | c.3079G>C p.E1027Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99603669; called by muse, mutect2, varscan2
- CEP350 | c.3656C>T p.S1219F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV62600529, COSV62607329; called by muse, mutect2
- CFAP221 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs750449699, COSV54654135, COSV99732337; called by muse, mutect2
- CHL1 | c.772T>A p.L258M (on ENST00000397491 / NM_001253387.1; = p.L274M on NM_006614.4) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769233255, COSV99849699; called by muse, mutect2, varscan2
- CHN1 | c.91C>G p.R31G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.524); catalogued as COSV101303540; called by muse, mutect2, varscan2
- CLIP3 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1211137414, COSV62113703, COSV62113752; called by muse, mutect2, varscan2
- CNKSR1 | c.1180C>T p.R394W (on ENST00000374253 / NM_001297647.2; = p.R387W on NM_006314.3) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458800107, COSV100836730; called by muse, mutect2
- CNTN2 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100084903; called by muse, mutect2, varscan2
- COBLL1 | c.1089G>A p.M363I (on ENST00000392717; = p.M325I on NM_014900.5) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV99527625, COSV99527760; called by muse, mutect2, varscan2
- COL17A1 | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100793138, COSV62225010; called by muse, mutect2, varscan2
- COL6A5 | c.6947C>T p.S2316L (on ENST00000312481; = p.S2312L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99592866; called by muse, mutect2
- CPXM2 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.545); catalogued as rs529727115, COSV53863911; called by mutect2, varscan2
- CRNN | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV55121600; called by muse, mutect2
- CRYBG1 | c.6319C>G p.Q2107E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100954147, COSV100954159; called by muse, mutect2, varscan2
- CSDE1 | c.2143G>A p.D715N (on ENST00000358528 / NM_001007553.3; = p.D684N on NM_007158.6) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99794728; called by muse, mutect2, varscan2
- CXCL17 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV99734044; called by muse, mutect2, varscan2
- DAB1 | c.1691C>G p.S564* (on ENST00000371231; = p.S531* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100976285; called by muse, mutect2
- DBH | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs766166337, COSV55039535; called by muse, mutect2, varscan2
- DEPDC1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100920277; called by muse, mutect2, varscan2
- DLX5 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.341); catalogued as rs773641315, COSV99756419; called by muse, mutect2, varscan2
- DMRT2 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99426036; called by muse, mutect2, varscan2
- DMXL1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs373143457, COSV60705358; called by muse, mutect2, varscan2
- DNAAF4 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100336697; called by muse, mutect2, varscan2
- DNAH1 | c.10496C>G p.S3499C | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV101325548; called by muse, mutect2
- DNAH11 | c.3010G>T p.D1004Y | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100175983, COSV60947459, COSV60981523; called by muse, mutect2
- DNAJB4 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.375); catalogued as COSV100883452; called by muse, mutect2, varscan2
- DOCK7 | c.5671G>A p.E1891K (on ENST00000635253 / NM_001367561.1; = p.E1860K on NM_033407.3) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99224067; called by muse, mutect2
- DUOX1 | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs899955788, COSV58485814; called by muse, mutect2, varscan2
- DUOX2 | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758697659, COSV101199706; called by muse, mutect2, varscan2
- ECD | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as COSV100881411; called by muse, mutect2, varscan2
- ECM1 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV100681888; called by muse, mutect2
- ECPAS | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV52195252, COSV52203560; called by muse, mutect2
- EEF1AKMT4 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99955524; called by muse, mutect2, varscan2
- ELOA2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764390730, COSV99796384; called by muse, mutect2, varscan2
- ELP1 | c.3569C>T p.S1190L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101010376; called by muse, mutect2
- EPHA1 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99313825; called by muse, mutect2
- ERCC6L | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100559081; called by muse, mutect2, varscan2
- ESPN | c.1208G>C p.R403T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV100911410; called by muse, mutect2, varscan2
- EXO1 | c.2367C>G p.I789M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV62219390; called by muse, mutect2, varscan2
- F8 | c.2598G>A p.M866I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100811453; called by muse, mutect2, varscan2
- FAIM2 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100277506; called by muse, varscan2
- FAM126B | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99627683; called by muse, mutect2
- FAM47C | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100792463, COSV63723899; called by muse, mutect2, varscan2
- FAM47C | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV100792465, COSV63730867; called by muse, mutect2, varscan2
- FBLN5 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.705); catalogued as rs760345539, COSV50902040; called by mutect2, varscan2
- FDPS | c.1036C>G p.P346A | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV52737977; called by muse, mutect2, varscan2
- FGFR2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as CM036118, COSV60651772; called by muse, mutect2, varscan2
- FJX1 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV100502651; called by muse, mutect2, varscan2
- FLNC | c.2755G>C p.E919Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV100367968; called by muse, mutect2
- FOXA3 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100141329, COSV56215032; called by muse, varscan2
- FRG1 | c.260-1del p.X87_splice | Splice Site (DEL) | VAF 7/41 reads (17%) | catalogued as rs1265231392; called by pindel*, varscan2
- FUBP1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99628460; called by muse, mutect2
- FZD4 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM106789, COSV101536041; called by muse, mutect2, varscan2
- GABBR2 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99409797; called by muse, mutect2
- GAD1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV100713805; called by muse, mutect2, varscan2
- GALNTL5 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV101217774; called by muse, mutect2, varscan2
- GLCE | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV55947184; called by muse, mutect2
- GLRA2 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.636); catalogued as COSV99490792; called by muse, mutect2
- GNAS | c.513G>C p.Q171H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV58347435; called by muse, mutect2, varscan2
- GNS | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV99253753; called by muse, mutect2, varscan2
- GPD1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99993767; called by muse, mutect2
- GPR108 | c.951C>G p.I317M (on ENST00000264080 / NM_001080452.1; = p.I75M on NM_020171.2) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901288; called by muse, mutect2, varscan2
- GRHPR | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1473836715, COSV100546900; called by muse, mutect2, varscan2
- GRIN2A | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs773569899, COSV58045765, COSV58056000; called by muse, mutect2, varscan2
- GTF3C4 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV100935988; called by muse, mutect2, varscan2
- HAGHL | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV52405908, COSV99284623; called by muse, mutect2, varscan2
- HEATR6 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); catalogued as COSV99482275; called by muse, mutect2, varscan2
- HGD | c.550-1G>C p.X184_splice | Splice Site (SNP) | VAF 3/50 reads (6%) | catalogued as COSV52201963; called by muse, mutect2
- HMCN2 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs371438649; called by muse, mutect2, varscan2
- HOXB2 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100344607; called by mutect2, varscan2
- HP1BP3 | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.963); catalogued as COSV100391754; called by muse, mutect2
- HSPA12A | c.1306T>A p.S436T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV100979770; called by muse, mutect2, varscan2
- HSPA8 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV99914349, COSV99914533; called by muse, mutect2, varscan2
- HYAL2 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51701560, COSV99222702; called by muse, mutect2
- IARS1 | c.2329A>G p.T777A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as COSV100986807; called by muse, mutect2, varscan2
- IL17RA | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.811); catalogued as COSV100083063; called by muse, mutect2
- INTS7 | c.1965G>A p.M655I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as COSV100877476; called by muse, mutect2, varscan2
- INVS | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV99317422; called by muse, mutect2
- INVS | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99317424; called by muse, mutect2, varscan2
- IP6K3 | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.844); catalogued as COSV99539782; called by muse, mutect2
- IRF2BPL | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99468015; called by muse, mutect2, varscan2
- ITPR1 | c.5370G>A p.M1790I (on ENST00000354582; = p.M1735I on NM_002222.7) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV100230787; called by muse, mutect2, varscan2
- KANK2 | c.1723G>A p.E575K (on ENST00000586659 / NM_001379562.1; = p.E583K on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100763165; called by muse, mutect2, varscan2
- KANSL1 | c.2358G>A p.M786I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV99294396, COSV99294720; called by muse, mutect2, varscan2
- KCNK3 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100256793, COSV57192758; called by muse, mutect2, varscan2
- KCNT1 | c.2365G>A p.E789K (on ENST00000488444; = p.E808K on NM_020822.3) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV53706008; called by muse, mutect2, varscan2
- KDM3B | c.4366G>A p.D1456N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.059); catalogued as rs745528581, COSV58690081; called by muse, mutect2, varscan2
- KIAA0319L | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV100357291; called by muse, mutect2, varscan2
- KIAA0586 | c.2230G>A p.D744N (on ENST00000619416 / NM_001244190.2; = p.D683N on NM_014749.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.775); catalogued as COSV99707967; called by mutect2, varscan2
- KMT2D | c.13076C>T p.S4359L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.095); catalogued as COSV56423074, COSV56430900; called by muse, mutect2
- KRT25 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100379900; called by muse, mutect2, varscan2
- KRTAP21-2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100441147, COSV61684150; called by muse, mutect2, varscan2
- L3MBTL2 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345824; called by muse, varscan2
- L3MBTL2 | c.1473G>C p.Q491H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV99345827; called by muse, varscan2
- LLCFC1 | c.210G>C p.E70D (on ENST00000458732; = p.E39D on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.555); catalogued as rs1410109887, COSV100787022; called by muse, mutect2, varscan2
- LMBRD2 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs754566151, COSV99682783, COSV99682909; called by muse, mutect2, varscan2
- LRP1B | c.8918C>T p.S2973F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs1355488159, COSV67269406; called by muse, mutect2, varscan2
- LY9 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99626600; called by muse, mutect2, varscan2
- MAB21L1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100079145, COSV59800406; called by muse, mutect2, varscan2
- MAGEA8 | c.956G>C p.*319Sext*42 | Nonstop Mutation (SNP) | VAF 26/176 reads (15%) | catalogued as COSV99674543; called by muse, mutect2, varscan2
- MAGIX | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100891871, COSV66255661; called by muse, mutect2, varscan2
- MAP2 | c.2978G>C p.G993A | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV99559406; called by muse, mutect2
- MAP2K1 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs754765552, COSV57234684; called by muse, mutect2, varscan2
- MAP7D2 | c.1882G>T p.D628Y | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101107322; called by muse, mutect2, varscan2
- MARK1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1417466721, COSV100857172; called by muse, mutect2
- MDGA2 | c.2851C>T p.H951Y (on ENST00000399232 / NM_001113498.2; = p.H653Y on NM_182830.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.3); catalogued as rs867368298, COSV100636934; called by muse, mutect2, varscan2
- MED14 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100247449; called by muse, mutect2
- MED16 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs556826884, COSV99515521; called by muse, mutect2, varscan2
- MED25 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100457294; called by muse, mutect2, varscan2
- MEGF10 | c.2480G>C p.R827T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99174870; called by muse, mutect2, varscan2
- MEPCE | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99439934; called by muse, mutect2
- METTL22 | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99371649; called by muse, mutect2
- MID1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV100452244, COSV58197978; called by muse, mutect2
- MTERF1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100699563; called by muse, mutect2
- MTPN | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.649); catalogued as COSV101262956; called by muse, mutect2, varscan2
- MUC3A | c.7940C>T p.S2647L | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs753787832, COSV100114479; called by muse, mutect2, varscan2
- MXRA5 | c.7186C>T p.Q2396* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99476641; called by muse, mutect2, varscan2
- MYH10 | c.4391C>G p.S1464C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52594365; called by muse, mutect2, varscan2
- MYH4 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99701054; called by muse, mutect2
- MYNN | c.1614G>C p.L538F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.048); catalogued as COSV100581961; called by muse, mutect2
- MYO18A | c.6149C>T p.T2050M | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs764644006, COSV100572174; called by muse, mutect2, varscan2
- NARS1 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as rs1169818125, COSV99900566; called by muse, mutect2, varscan2
- NASP | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as COSV100601749; called by muse, mutect2
- NECAB1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV101341056; called by muse, mutect2, varscan2
- NEK11 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100797705; called by muse, mutect2, varscan2
- NFATC1 | c.2001G>C p.R667S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.843); catalogued as COSV99501386; called by muse, mutect2
- NIBAN1 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.337); catalogued as COSV100836378, COSV62283265; called by muse, mutect2
- NLRP1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs373530609; called by muse, mutect2, varscan2
- NLRP1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.12); catalogued as rs766538219, COSV99333875; called by muse, mutect2, varscan2
- NME4 | c.330C>T p.V110= | Splice Region (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99556761; called by muse, mutect2, varscan2
- NOTCH2 | c.3916G>A p.D1306N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.066); catalogued as rs116408209; ClinVar: uncertain significance; called by muse, mutect2
- NPBWR1 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV100488192; called by muse, mutect2, varscan2
- NRG1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.042); catalogued as COSV99828277; called by muse, mutect2, varscan2
- NWD1 | c.3136G>C p.E1046Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV100342430, COSV60352058; called by muse, mutect2
- ODF2L | c.373-1G>A p.X125_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99644074; called by muse, mutect2, varscan2
- OR2L2 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV100823484, COSV63553116; called by muse, mutect2
- OTOGL | c.3775C>G p.P1259A (on ENST00000547103; = p.P1250A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.288); catalogued as COSV101509177; called by muse, mutect2
- PASD1 | c.2027C>G p.S676* | Nonsense Mutation (SNP) | VAF 8/99 reads (8%) | catalogued as COSV100949284; called by muse, mutect2
- PAXBP1 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99269223; called by muse, mutect2, varscan2
- PCCA | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.933); catalogued as COSV100883559; called by muse, mutect2, varscan2
- PCDHB1 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs180731232, COSV60629496, COSV60633816; called by muse, mutect2, varscan2
- PCDHB16 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs374286802; called by muse, mutect2, varscan2
- PCDHGB7 | c.2389G>C p.E797Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.084); catalogued as COSV99536305; called by muse, mutect2, varscan2
- PCGF6 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100461915; called by muse, mutect2, varscan2
- PDLIM5 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV58746525; called by muse, mutect2, varscan2
- PDXDC1 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.576); catalogued as COSV99816884; called by muse, mutect2
- PEA15 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100470354; called by muse, mutect2, varscan2
- PEX5L | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.037); catalogued as COSV99828469; called by muse, varscan2
- PHYKPL | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1454230974, COSV100069521; called by muse, mutect2, varscan2
- PIP4K2C | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV100723899; called by muse, mutect2, varscan2
- PIP5K1A | c.118G>A p.E40K (on ENST00000368888 / NM_001135638.2; = p.E39K on NM_003557.3) | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as COSV100576596; called by muse, mutect2
- PLCB2 | c.1083G>T p.W361C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53034616; called by muse, mutect2, varscan2
- PLCG2 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749548361, COSV100842179, COSV100842216; called by muse, mutect2, varscan2
- PLS1 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100538066; called by muse, mutect2, varscan2
- PLXNA2 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.289); catalogued as COSV100885380, COSV100886164; called by muse, mutect2
- POGZ | c.2738C>G p.S913* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as COSV99304980; called by muse, mutect2
- POLR1A | c.4006G>A p.E1336K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as rs1401378860, COSV99807465; called by muse, mutect2, varscan2
- POM121 | c.1144G>A p.D382N (on ENST00000434423; = p.D117N on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV99988143; called by muse, mutect2, varscan2
- POPDC3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs757703112, COSV54643635, COSV54643704, COSV54644363; called by muse, mutect2, varscan2
- PPARG | c.489C>G p.F163L (on ENST00000287820 / NM_015869.5; = p.F133L on NM_005037.7) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV99826418; called by muse, mutect2, varscan2
- PPP2CA | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as rs929459974, COSV99196036; called by muse, mutect2
- PRAMEF2 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV99535194; called by muse, mutect2
- PRCC | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV54858009; called by muse, mutect2, varscan2
- PREX2 | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs866381944, COSV99906618; called by muse, mutect2, varscan2
- PROX1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV99799166; called by muse, mutect2
- PRPF39 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.12); catalogued as COSV100866005; called by muse, mutect2, varscan2
- PSMB5 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.97); catalogued as COSV57800175; called by muse, mutect2
- PSMD3 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV99227756; called by muse, mutect2, varscan2
- PSMD7 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV99542703; called by muse, mutect2
- PTPRG | c.663G>C p.L221F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99874437; called by muse, mutect2, varscan2
- PTPRG | c.1815G>C p.K605N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99874440; called by mutect2, varscan2
- PTPRR | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs1454424176, COSV99317142; called by muse, mutect2, varscan2
- QRICH2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); catalogued as rs1331933349, COSV99429133; called by muse, mutect2
- RAB3GAP1 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99920972; called by muse, mutect2
- RAD54B | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60251399; called by muse, mutect2, varscan2
- RALGPS1 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401451; called by muse, mutect2, varscan2
- RANGRF | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs552055941, COSV56839758; called by muse, mutect2, varscan2
- RASGRF1 | c.270G>C p.E90D | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV101369603; called by muse, mutect2, varscan2
- RASGRP3 | c.1280C>T p.S427F (on ENST00000402538 / NM_001349975.2; = p.S426F on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101274739; called by muse, mutect2, varscan2
- RCOR2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV56850637; called by muse, mutect2
- RERE | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100555925; called by muse, mutect2, varscan2
- RGS6 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs755501563, COSV100665916; called by muse, mutect2, varscan2
- RIPOR3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1052202968, COSV99246266; called by muse, mutect2, varscan2
- RNPEPL1 | c.1230G>C p.Q410H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.967); catalogued as COSV99549455; called by muse, mutect2, varscan2
- ROCK2 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.028); catalogued as COSV100254723; called by muse, mutect2, varscan2
- RPL3L | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs530918397, COSV51905287; called by muse, mutect2, varscan2
- RPS6KA6 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53120945, COSV99424604; called by muse, mutect2, varscan2
- RTL9 | c.1890G>C p.E630D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV101511671, COSV71825896; called by muse, mutect2
- SASH1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100821146; called by muse, mutect2, varscan2
- SASH1 | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as rs1276391094, COSV100821148; called by muse, mutect2, varscan2
- SBNO2 | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100684414; called by muse, mutect2, varscan2
- SCN5A | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs368552426, CM094264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC22A | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100006946; called by muse, mutect2, varscan2
- SEC23B | c.1641G>A p.W547* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as rs779322575, COSV99357626; called by muse, mutect2, varscan2
- SELENBP1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100923631; called by muse, mutect2
- SENP7 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100052956; called by muse, mutect2, varscan2
- SEPHS2 | c.549G>C p.M183I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV101529312; called by muse, mutect2, varscan2
- SERTAD1 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV63596285; called by muse, mutect2, varscan2
- SETD7 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV99918450; called by mutect2, varscan2
- SGSM3 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99960345; called by muse, mutect2
- SH3BP5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs770323940, COSV99508216; called by muse, mutect2, varscan2
- SI | c.5228T>A p.V1743E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV100015184; called by muse, mutect2, varscan2
- SLC30A4 | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99970223; called by muse, mutect2, varscan2
- SLC30A5 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV101173584; called by muse, mutect2, varscan2
- SLC35B2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs772679565, COSV99241053; called by muse, mutect2, varscan2
- SLITRK1 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV65677893; called by muse, mutect2, varscan2
- SLITRK4 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.428); catalogued as COSV100567291; called by muse, mutect2
- SLMAP | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs146606397; called by muse, mutect2, varscan2
- SMARCC1 | c.3277C>G p.P1093A | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.068); catalogued as COSV99592688; called by muse, mutect2, varscan2
- SMC1A | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs782175064, COSV59128996; called by muse, mutect2
- SMC1A | c.1248G>C p.E416D | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as COSV100447299; called by muse, mutect2, varscan2
- SMG5 | c.1457C>G p.S486* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100700763; called by muse, mutect2, varscan2
- SPAM1 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56145828, COSV99772967; called by mutect2, varscan2
- SPG11 | c.6079C>T p.Q2027* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV55990213; called by muse, mutect2, varscan2
- SRSF2 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); catalogued as COSV100333790, COSV100334351; called by muse, varscan2
- STAG1 | c.3175G>A p.D1059N | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99365196; called by muse, mutect2, varscan2
- STAG1 | c.1053G>C p.L351F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99365198; called by muse, mutect2
- STAT4 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); catalogued as rs1356413880, COSV100636042; called by muse, mutect2
- STUB1 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as CM152046, COSV99555613; called by muse, mutect2, varscan2
- STYXL2 | c.2965G>A p.D989N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); catalogued as COSV99609065; called by muse, mutect2, varscan2
- SUCLG2 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs377513332; called by mutect2, varscan2
- SYNE1 | c.19429C>T p.H6477Y (on ENST00000367255 / NM_182961.4; = p.H6406Y on NM_033071.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV99561332; called by muse, mutect2, varscan2
- SYNE3 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1225363469, COSV100515905; called by muse, mutect2, varscan2
- TAF4B | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99300096; called by muse, mutect2
- TARBP1 | c.3490C>G p.L1164V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV99241498; called by muse, mutect2, varscan2
- TFAP4 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.827); catalogued as COSV99200048; called by muse, mutect2, varscan2
- THBD | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs200712265, COSV101001873; called by muse, mutect2, varscan2
- THSD7B | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV99748976; called by muse, mutect2, varscan2
- TLR1 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV100458452; called by muse, mutect2, varscan2
- TMEM145 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100003776; called by muse, mutect2
- TMEM182 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV101305328, COSV101305364; called by muse, mutect2
- TP53 | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV52729268, COSV52968197, COSV53108458; called by muse, mutect2, varscan2
- TPST1 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.067); catalogued as COSV100507036; called by muse, mutect2, varscan2
- TRDN | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1290263988, COSV62122396, COSV99043833; called by muse, mutect2, varscan2
- TRMT6 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99177558; called by muse, mutect2
- TRPC4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1366486478, COSV59012660; called by muse, mutect2, varscan2
- TRPV2 | c.776C>G p.S259* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100641185, COSV58428145; called by muse, mutect2, varscan2
- TRPV4 | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99924613; called by muse, mutect2, varscan2
- TTN | c.63622G>T p.E21208* (on ENST00000591111; = p.E13784* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100607698; called by muse, mutect2
- TULP1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as rs760988046, COSV100004084; called by muse, mutect2, varscan2
- TUSC3 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101141155; called by muse, mutect2, varscan2
- UBE2B | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.441); catalogued as COSV99530273; called by muse, mutect2
- UBR4 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.745); catalogued as COSV100920700; called by muse, mutect2, varscan2
- UHRF1BP1L | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.816); catalogued as COSV99691469; called by muse, mutect2
- USF3 | c.3976G>C p.D1326H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100325117, COSV57076114; called by muse, mutect2, varscan2
- USP15 | c.1867G>A p.E623K (on ENST00000280377 / NM_001351159.2; = p.E594K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV54790282, COSV99739256; called by muse, mutect2, varscan2
- USP2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV52733031; called by muse, mutect2, varscan2
- USP24 | c.4733C>T p.S1578L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs867800241, COSV99599470; called by muse, mutect2, varscan2
- USP54 | c.2774C>T p.S925L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.015); catalogued as COSV100357322; called by muse, mutect2
- USPL1 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV99687211; called by muse, mutect2, varscan2
- USPL1 | c.3122C>G p.S1041C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99687214; called by muse, mutect2, varscan2
- UTP15 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV57147945; called by muse, mutect2, varscan2
- VIPAS39 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV99375940; called by muse, mutect2, varscan2
- VIT | c.877G>A p.D293N (on ENST00000389975 / NM_001177969.1; = p.D308N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007354; called by muse, mutect2, varscan2
- VPS13B | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100661752; called by muse, mutect2, varscan2
- VPS13C | c.1969G>C p.E657Q (on ENST00000644861 / NM_020821.3; = p.E614Q on NM_017684.5) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as COSV99828216; called by muse, mutect2, varscan2
- VPS13D | c.10543C>T p.P3515S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV50635744; called by muse, mutect2
- VPS52 | c.700-1G>C p.X234_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101460425, COSV101460457; called by muse, mutect2
- WDR6 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs542788663, COSV58248409; called by muse, mutect2, varscan2
- XPNPEP1 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100450958; called by muse, mutect2, varscan2
- YLPM1 | c.3994C>T p.P1332S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as rs1422055018, COSV99459369; called by muse, mutect2
- ZBP1 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.171); catalogued as COSV100473350; called by muse, mutect2
- ZBTB26 | c.1325G>C p.*442Sext*28 | Nonstop Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV101021061; called by muse, mutect2, varscan2
- ZBTB26 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV101021062; called by muse, mutect2, varscan2
- ZNF232 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs766019408, COSV100005646; called by muse, mutect2, varscan2
- ZNF300 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV99199850; called by muse, mutect2, varscan2
- ZNF366 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.143); catalogued as COSV100574211; called by muse, mutect2, varscan2
- ZNF543 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100386737, COSV104395558; called by muse, mutect2, varscan2
- ZNF649 | c.766C>G p.H256D | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100030972; called by muse, mutect2, varscan2
- ZNF768 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99411447, COSV99411461; called by muse, mutect2, varscan2
- ZNF792 | c.1629C>G p.F543L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101289695; called by muse, mutect2, varscan2
- ZNF813 | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV101124812, COSV67176924; called by muse, mutect2, varscan2
- ZPR1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99911275; called by muse, varscan2
- FEM1A | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- GPR179 | c.4351G>A p.E1451K (on ENST00000621958; = p.E1450K on NM_001004334.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- HMCN1 | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCL | c.741_758del p.D248_D253del | In Frame Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- USPL1 | c.917_929del p.T306Kfs*18 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ABCB1 | c.2832C>T p.F944= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99712802; called by muse, mutect2, varscan2
- ADCY10 | c.2250C>T p.L750= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as rs143102400, COSV63239503; called by muse, mutect2
- ADGRB2 | c.2910G>A p.L970= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99926092; called by muse, mutect2, varscan2
- AGBL1 | c.2886G>A p.E962= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV66865227, COSV66869636; called by muse, mutect2, varscan2
- AGR2 | c.447C>T p.L149= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs767394089, COSV101290812; called by muse, mutect2, varscan2
- ALOXE3 | c.1404C>T p.I468= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs781376374, COSV59075539; called by muse, mutect2, varscan2
- AMN | c.729C>T p.L243= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100141493; called by muse, mutect2
- ANKS6 | c.1662G>A p.L554= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV62049787, COSV62051944; called by muse, mutect2, varscan2
- APLNR | c.369C>G p.L123= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99951405, COSV99951717; called by muse, mutect2, varscan2
- ARHGAP39 | c.2319G>A p.K773= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99430929; called by muse, mutect2, varscan2
- ARID2 | c.1563G>A p.E521= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100535972; called by muse, mutect2, varscan2
- ASXL3 | c.4617C>T p.F1539= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99324555; called by muse, mutect2
- ATF3 | c.201C>T p.V67= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100421999; called by muse, mutect2, varscan2
- BTN2A2 | c.1347C>T p.F449= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV61857471; called by muse, mutect2
- BTNL8 | c.1095G>A p.R365= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99180462; called by muse, mutect2, varscan2
- CAAP1 | c.9G>A p.G3= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as rs947411094, COSV100445112; called by muse, mutect2, varscan2
- CACNA1E | c.2307G>A p.R769= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV62383333; called by muse, mutect2
- CAMSAP3 | c.3189C>G p.L1063= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV50330892, COSV99350467; called by muse, mutect2
- CCDC15 | c.1417C>T p.L473= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100776956; called by muse, mutect2, varscan2
- CDC42BPB | c.645C>G p.R215= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100775379; called by muse, mutect2, varscan2
- CELA2B | c.186G>A p.L62= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV101025765; called by muse, mutect2, varscan2
- CEP250 | c.498C>T p.F166= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100698883, COSV99062576; called by muse, mutect2, varscan2
- CFAP251 | c.1617G>A p.L539= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99996017; called by muse, mutect2, varscan2
- CFAP251 | c.1797G>A p.E599= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99996018; called by muse, mutect2, varscan2
- CLPS | c.338G>A p.*113= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as COSV99463606, COSV99463707; called by muse, mutect2
- COL4A5 | c.1503C>T p.L501= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV60371801; called by muse, mutect2, varscan2
- CWH43 | c.63C>G p.L21= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99893277; called by muse, mutect2, varscan2
- CXXC1 | c.1086G>A p.E362= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1219975425, COSV99496096; called by muse, mutect2, varscan2
- DAXX | c.327C>G p.L109= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99801976; called by muse, mutect2
- DGAT2L6 | c.627G>A p.V209= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100283956; called by muse, mutect2, varscan2
- DGKD | c.1179C>A p.L393= (on ENST00000264057 / NM_152879.3; = p.L349= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV51092899, COSV99896118; called by muse, mutect2, varscan2
- DMD | c.5778G>A p.L1926= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100819211; called by muse, mutect2, varscan2
- DNA2 | c.2757C>G p.L919= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100622524; called by muse, mutect2, varscan2
- DNM2 | c.603C>T p.I201= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs980931289, COSV100117116; called by muse, mutect2, varscan2
- ECI2 | c.1155G>A p.V385= (on ENST00000380118 / NM_206836.3; = p.V355= on NM_006117.2) | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100326431; called by muse, mutect2, varscan2
- EN2 | c.975C>T p.A325= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99818604; called by muse, mutect2, varscan2
- FAM71B | c.357C>T p.L119= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs1316893066, COSV100262051; called by muse, mutect2, varscan2
- FASN | c.5160C>T p.F1720= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs138389856, COSV100147508; called by muse, mutect2, varscan2
- FCSK | c.2058G>A p.V686= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99850776; called by muse, mutect2, varscan2
- FLAD1 | c.510C>T p.F170= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV99422397; called by muse, mutect2, varscan2
- FREM1 | c.3510C>T p.I1170= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs989744495, COSV66533850; called by muse, mutect2
- GALP | c.48G>A p.L16= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs778263756, COSV100627946; called by muse, mutect2, varscan2
- GALT | c.396C>T p.H132= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as rs367543256, CM125422, COSV101122750; called by muse, mutect2, varscan2
- GJB1 | c.705C>T p.F235= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs760150310, COSV100661265; called by muse, mutect2, varscan2
- GPC2 | c.762G>C p.L254= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs1255179137, COSV99444635; called by muse, mutect2, varscan2
- GPR17 | c.1044G>A p.P348= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs375979218; called by muse, mutect2, varscan2
- GYS1 | c.264G>A p.K88= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99620683; called by muse, varscan2
- GYS1 | c.219G>A p.V73= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99620685; called by muse, varscan2
- H2BC8 | c.282G>A p.E94= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV55125995; called by muse, mutect2
- H3C2 | c.174G>T p.S58= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV52519150; called by muse, mutect2, varscan2
- HENMT1 | c.324C>T p.I108= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100898652; called by muse, mutect2, varscan2
- HGS | c.948G>A p.A316= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs371235729; called by muse, mutect2, varscan2
- HSPB9 | c.444G>T p.G148= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99863512; called by muse, mutect2, varscan2
- ICOS | c.195C>G p.L65= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100320316; called by muse, mutect2, varscan2
- INSRR | c.1332C>T p.F444= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100947426; called by muse, mutect2, varscan2
- KANSL1 | c.2397G>A p.L799= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV99294395; called by muse, mutect2, varscan2
- KCNH7 | c.1674C>T p.I558= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100035451; called by muse, mutect2, varscan2
- KIAA0100 | c.1119G>C p.L373= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV101197287; called by muse, mutect2, varscan2
- KIF20B | c.4626G>A p.Q1542= (on ENST00000371728 / NM_001284259.2; = p.Q1502= on NM_016195.4) | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99589863; called by muse, mutect2, varscan2
- KPRP | c.1110G>A p.L370= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100908694; called by muse, mutect2, varscan2
- KRT36 | c.447T>C p.D149= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100057470; called by muse, mutect2, varscan2
- MAFB | c.81C>G p.L27= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs766706300, COSV64826785; called by muse, mutect2
- MAP2 | c.471G>C p.S157= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99559405; called by muse, mutect2, varscan2
- MAS1 | c.597C>T p.F199= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1194833964, COSV53120813; called by muse, mutect2, varscan2
- MCM3AP | c.1785G>A p.L595= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs374057302, COSV52447396; called by muse, mutect2, varscan2
- MSH4 | c.2103G>A p.Q701= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99591409; called by muse, mutect2, varscan2
- MTM1 | c.51G>A p.E17= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs148455726, COSV100080374; called by muse, mutect2
- MUC16 | c.36366C>T p.L12122= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV101198072; called by muse, mutect2, varscan2
- MUC17 | c.9840C>T p.S3280= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs1402803430, COSV100072831; called by muse, mutect2, varscan2
- MYH4 | c.3450C>T p.I1150= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV55112060; called by muse, mutect2, varscan2
- NAA35 | c.1728C>T p.I576= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100863320; called by muse, mutect2, varscan2
- NEK11 | c.297G>A p.V99= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100797698, COSV100797836; called by muse, mutect2, varscan2
- NEU1 | c.633G>A p.R211= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs769537274, COSV99998873; called by muse, mutect2
- NUP188 | c.4989C>T p.I1663= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV100999342; called by muse, mutect2, varscan2
- OLFM1 | c.993C>G p.L331= (on ENST00000371793 / NM_001282611.2; = p.L313= on NM_014279.5) | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs951401088, COSV53277540; called by muse, mutect2, varscan2
- OR52I2 | c.384C>T p.F128= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV100442887; called by muse, mutect2, varscan2
- OR5H2 | c.270C>T p.F90= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100788702, COSV62350300; called by muse, mutect2, varscan2
- OR5L1 | c.282C>T p.F94= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV100449934, COSV61735384; called by muse, mutect2, varscan2
- OR6B2 | c.555C>G p.L185= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99401388; called by muse, mutect2, varscan2
- OR6X1 | c.312C>T p.F104= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs772751788, COSV60010140; called by muse, mutect2, varscan2
- OR7E24 | c.93C>T p.L31= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV71702135; called by muse, mutect2, varscan2
- PAPPA | c.1104G>A p.P368= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1232382704, COSV60291676; called by muse, mutect2, varscan2
- PCCB | c.672C>T p.F224= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99291267; called by muse, mutect2, varscan2
- PID1 | c.624C>T p.A208= (on ENST00000354069 / NM_001330156.1; = p.A206= on NM_017933.5) | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV100819612; called by muse, mutect2
- PLCH2 | c.3465C>G p.V1155= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as COSV99616095; called by muse, mutect2, varscan2
- POLR2J | c.21C>T p.F7= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV99484486; called by muse, varscan2
- POSTN | c.2139G>A p.L713= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs748096412, COSV101123310; called by muse, mutect2, varscan2
- PPID | c.702C>T p.F234= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100306798; called by muse, mutect2, varscan2
- PPP1R9A | c.2250C>G p.L750= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99195378; called by muse, mutect2
- PTAR1 | c.1146G>A p.R382= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV100466435; called by muse, mutect2
- PYGB | c.2070C>T p.I690= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as rs778626594, COSV99405028; called by muse, mutect2, varscan2
- RGS7 | c.1165C>T p.L389= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100466619; called by muse, mutect2, varscan2
- RRP8 | c.1335C>T p.G445= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1322405026, COSV99601879; called by muse, mutect2, varscan2
- RSRC2 | c.495G>A p.S165= | Silent (SNP) | VAF 21/168 reads (13%) | catalogued as rs572371574, COSV100063500; called by muse, mutect2, varscan2
- SAG | c.1161G>A p.L387= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV101300663; called by muse, mutect2, varscan2
- SETD2 | c.6186G>A p.E2062= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100338785; called by muse, mutect2, varscan2
- SH3BGRL | c.210C>T p.F70= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100943334; called by muse, mutect2, varscan2
- SHOX2 | c.945C>A p.I315= (on ENST00000441443 / NM_006884.3; = p.I339= on NM_003030.4) | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV101273762, COSV101273775; called by muse, mutect2, varscan2
- SLC17A6 | c.1152G>A p.V384= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99581301; called by muse, mutect2, varscan2
- SLC2A1 | c.1350C>T p.F450= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100995850; called by muse, mutect2, varscan2
- SLC4A5 | c.2232G>A p.A744= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs775514122, COSV61032671; called by muse, mutect2, varscan2
- SLC5A4 | c.960G>A p.L320= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99831868; called by muse, mutect2
- SLC7A8 | c.930C>G p.L310= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100328383; called by muse, mutect2, varscan2
- STON1 | c.621C>T p.F207= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV59140856; called by muse, mutect2
- SWI5 | c.174C>T p.F58= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs1194890115, COSV100199631; called by muse, mutect2, varscan2
- TAP1 | c.2289C>G p.L763= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100841180; called by muse, mutect2, varscan2
- TBC1D4 | c.1203C>T p.I401= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100884583; called by muse, mutect2
- TENM1 | c.7741C>T p.L2581= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV100949775; called by muse, mutect2
- TLE2 | c.969C>T p.L323= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV99504247; called by muse, varscan2
- TMEM38A | c.342G>T p.V114= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV99495236; called by muse, mutect2, varscan2
- TNKS | c.666C>T p.F222= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV60052048; called by muse, mutect2
- TNXB | c.8967G>C p.L2989= (on ENST00000647633; = p.L2742= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100926212, COSV64490483; called by muse, mutect2, varscan2
- TPH1 | c.768G>A p.V256= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV100000796; called by muse, mutect2, varscan2
- TRIM73 | c.117C>T p.C39= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV51903969; called by muse, mutect2, varscan2
- TRPA1 | c.2448C>A p.I816= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100083926; called by muse, mutect2, varscan2
- ULK3 | c.1263G>A p.R421= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV101475543; called by muse, mutect2
- VARS1 | c.12C>T p.L4= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100989547; called by muse, mutect2
- ZNF16 | c.1176G>C p.L392= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52765188, COSV99429598; called by muse, mutect2, varscan2
- ZNF479 | c.1470G>A p.E490= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100482754, COSV58637090; called by muse, mutect2, varscan2
- ZNF543 | c.90G>A p.Q30= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV100386736; called by muse, mutect2, varscan2
- ZNF629 | c.999G>A p.L333= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1232681382, COSV99354727; called by muse, mutect2
- ABHD14A-ACY1 | chr3:51977882 G>C | 5'Flank (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99865373; called by muse, mutect2
- C9orf106 | n.420C>T | RNA (SNP) | VAF 5/36 reads (14%) | catalogued as rs1409703713; called by muse, mutect2, varscan2
- CD47 | c.*3G>A | 3'UTR (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100790114; called by muse, mutect2
- DLG2 | c.205-65604C>T | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54632792; called by muse, mutect2, varscan2
- MACROD2 | c.164-33690C>G | Intron (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397668 C>T | 3'Flank (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2, varscan2
- OR2W5 | n.1060C>T | RNA (SNP) | VAF 15/113 reads (13%) | catalogued as rs867029459; called by muse, mutect2, varscan2
- RPGR | c.2520+334G>C | Intron (SNP) | VAF 11/105 reads (10%) | catalogued as COSV100139895; called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6288A>G | Intron (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100217824; called by muse, mutect2, varscan2
- TTN | c.34264+2979G>A | Intron (SNP) | VAF 10/61 reads (16%) | catalogued as rs878854299, COSV100607715; called by muse, mutect2, varscan2
